Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1XR, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1XR-01A (Primary Tumor).

Department of Cancer Pathology

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Multiple organ resection – right breast with axillary tissues

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: up to 8 working days

Clinical diagnosis: Cancer of the right breast.

ICD-0-3

carcinoma, infiltrating duct, nos 8500/

Site: breast, nos C50.9
4/12/11

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei.

Progesterone receptors found in over 75% of neoplastic cell nuclei.

HER2 protein stained with HercepTest™ by DAKO. Negative reaction in invasive cancerous cells (Score = 1+).

Compliance validated by:

Examination performed on:

Macroscopic description:

Right breast sized 26 x 17 x 7 cm removed along with axillary tissues sized 10 x 14 x 6 cm and a skin flap of 16 x 8 cm. Tumour sized 3.2 x 2.5 x 1.9 cm in the upper outer quadrant, located 4.5 cm from the upper boundary, 1.7 cm from the base and 1.2 cm from the skin.

Seven separate pieces with 3 x 2 x 1 cm in total.

Microscopic description:

Carcinoma ductale invasivum NHG2 (2 + 3 + 1/15 mitoses/10 HPF - visual area 0.55 mm). Extensive fibrosis in the central part of the tumour. Numerous signet ring cells. Mamilla sine laesionibus.

Glandular tissue showing lesions of the type mastopathia fibrosa et lipomatosis.

Axillary lymph nodes: Metastases carcinomatosae in lymphonodis (No II/VII).

Histopathological diagnosis:**Invasive ductal carcinoma of the right breast**

Metastases carcinomatosae in lymphonodis axillae (No II/VII). (NHG2; pT2; pN1a). Cancer metastases in axillary lymph nodes.

Compliance validat

CONTACT YOUR DOCTOR WITH THIS REPORT!

Dual/Synchronous Primary	Noted	

Source: NCI Genomic Data Commons file 1352674a-5770-4b39-9de7-6f9e60fe96b2 (TCGA-D8-A1XR.D9A0E659-99BC-4704-AC85-E63098BA731D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).